Surgical pathology report (de-identified scan), TCGA case TCGA-G9-A9S7, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G9-A9S7-01A (Primary Tumor).

[page 1 of 2]
Surg Date

SPECIMENS:

- A. LEFT PELVIC LYMPH NODES
- B. RIGHT PELVIC LYMPH NODES
- C. PROSTATE

SPECIMEN(S):

- A. LEFT PELVIC LYMPH NODES
- B. RIGHT PELVIC LYMPH NODES
- C. PROSTATE

DIAGNOSIS:

- A. LYMPH NODE, LEFT PELVIC, EXCISION:
- SIX LYMPH NODES, NEGATIVE FOR CARCINOMA (0/6)
- B. LYMPH NODE, RIGHT PELVIC, EXCISION:
- TWO LYMPH NODES, NEGATIVE FOR CARCINOMA (0/2)
- C. PROSTATE, PROSTATECTOMY:
- PROSTATIC ADENOCARCINOMA, GLEASON SCORE 4 + 4 = 8/10
- TUMOR INVOLVING APPROXIMATELY 15% OF TISSUE EXAMINED
- MULTIFOCAL EXTRAPROSTATIC EXTENSION IDENTIFIED (RIGHT POSTERIOR AND ANTERIOR, LEFT APEX)
- SEMINAL VESICLES NOT INVOLVED BY THE TUMOR
- SURGICAL MARGINS NEGATIVE FOR TUMOR
- SEE SYNOPTIC REPORT

SYNOPTIC REPORT - PROSTATE GLAND

Specimens Involved

Specimens: C: PROSTATE

Location: Left

Right

Posterior lateral

Apical

Anterior

WHO CLASSIFICATION

Epithelial tumors

Adenocarcinoma 8140/3

Multicentricity: Yes

Gland Involvement: 15%

Gleason Grade/Sum:: Grade 4 + 4 , Sum 8

High Grade PIN Present: Yes

Perineural Invasion: Yes

Vascular/Lymphatic Invasion: No

Seminal Vesicle Invasion: No

Periprostatic Fat Involved: Yes

Details: right posterior and anterior, left apex

Bladder Neck Involved: No

Margins Involvement: No

Frozen Performed: No

Lymph Nodes: Negative Right 0 / 2 Left 0 / 6

Other Pathologic Findings: BPH

Pathological Staging (pTNM): T 3a N 0 M X

Pathological staging is based on the AJCC Cancer Staging Manual, 7th Edition

GROSS DESCRIPTION:

- A. LEFT PELVIC LYMPH NODES

ICD O-3

Adeno carcinoma NOS 8140/3

Site: Prostate NOS C619

9/10/14

[page 2 of 2]
Surg Date

Received fresh labeled with the patient's identification and "left pelvic lymph node" are pieces of yellow-tan soft tissue, containing lymph nodes ranging from 0.5 x 0.5 x 0.3 cm to 2.0 x 1.7 x 0.6 cm; lymph nodes are submitted entirely:

A1: 5 lymph nodes

A2: 1 bisected lymph node

B. RIGHT PELVIC LYMPH NODES

Received fresh labeled with patient's identification and "right pelvic lymph node" are pieces of yellow-tan soft tissue in aggregate, 4.6 x 3.3 x 1.1 cm containing 2 lymph nodes, 1.5 x 1.2 x 1 cm in 0.8 x 1.2 x 0.6 cm. The lymph nodes are bisected and submitted entirely:

B1-B2: 1 bisected lymph node in each cassette

C. PROSTATE

Received fresh labeled with patient's identification and "prostate" is a 72 g resected prostate gland measuring 5.4 cm from right lateral to left lateral, 3.8 cm from anterior to posterior, and 3.4 cm from apex to base. The capsule is smooth, red, and intact. Ink code: Apex-red, base-blue, anterior-orange, posterior-black, right lateral-green, left lateral-yellow. After removal of apex and base, the prostate weighs 42 g and has a nodular tan parenchyma. The right seminal vesicle is 1.2 x 0.9 x 0.7 cm, the left is 2.5 x 1.7 x 0.5 cm, and a detached piece is 2.1 x 1.1 x 0.5 cm; they consist of cystic tan tissue. The right vas deferens is 2.6 x 0.5 cm and the left is 3.2 x 0.4 cm; they consist of tubular tan tissue. Tissue is procured (18 g); submitted entirely:

C1-C2: right apex

C3-C4: left apex

C5: level I, right anterior

C6: level I, right posterior

C7: level I, left anterior

C8: level I, left posterior

C9: level II, right anterior capsule

C10: level II, right posterior capsule

C11: level II, left anterior capsule

C12: level II, left posterior capsule

C13: level III, right anterior

C14: level III, right posterior

C15: level III, left anterior

C16: level III, left posterior

C17: level IV, right capsule

C18: level IV, left capsule

C19-C21: perpendicular sections of right lateral base

C22-C25: perpendicular sections left lateral base

C26-C27: perpendicular sections of right mid base

C28-C29: perpendicular sections of left mid base

C30: perpendicular sections of right posterior base

C31: perpendicular sections of left posterior base

C32: perpendicular section of right mid base urethral orifice margin

C33: perpendicular section of left mid base urethral orifice margin

C34: right seminal vesicle and vas deferens

C35: left seminal vesicle and vas deferens

C36: detached seminal vesicle

CLINICAL HISTORY:

None Given

PRE-OPERATIVE DIAGNOSIS:

Prostate cancer

Gross Dictation: , ,

Microscopic/Diagnostic Dictation, M.D., Pathologist,

Microscopic/Diagnostic Dictation: M.D., ,

Final Review: M.D., Pathologist,

Final: M.D., Pathologist,

Source: NCI Genomic Data Commons file d40bd098-e1ed-4756-9293-5ce47998718b (TCGA-G9-A9S7.32AD969B-10BB-4FA2-872B-D789382CD3CC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).